Gene-level copy-number profile of tumor specimen TARGET-20-PARUWX-09A from TARGET case TARGET-20-PARUWX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,049 days).
Specimen TARGET-20-PARUWX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.d3307402-988f-56a6-8568-272b767782c0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARUWX-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 418 have no estimate.
https://portal.gdc.cancer.gov/files/941cc202-7fa6-4751-830c-47c9bd3f369a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,428; copy number 1: 29; copy number 2: 54,868; copy number 3: 164; copy number 4: 2,582; copy number 6: 47; copy number 7: 5; copy number 11: 26; copy number 13: 56.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,906,757–90,235,370, 30 genes: IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr9:60,914,407–61,627,683, 15 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr17:41,265,339–41,271,835, 2 genes: KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 134 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 11 (within-gene range 2–11): AC244205.1.
- chr2:88,857,161–89,129,483, 25 genes, copy number 11: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18.
- chr14:105,736,343–106,360,324, 103 genes, copy number 6–13 (broad region; genes not listed).
- chr17:36,072,866–36,177,510, 5 genes, copy number 7 (within-gene range 2–7): AC243829.4, CCL3, CCL4, RN7SL301P, AC243829.2.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
